Somatic mutation profile of tumor specimen TARGET-10-PARCDX-09A (aliquot TARGET-10-PARCDX-09A-01D) from TARGET case TARGET-10-PARCDX, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.0 years (1,476 days).
Specimen TARGET-10-PARCDX-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) daa4272f-569c-41f4-8bb3-cfa9eca4a741.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARCDX-10A (Blood Derived Normal), aliquot TARGET-10-PARCDX-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c547a4e5-1b4a-4083-ad5e-77fa957c8e32

The open-access MAF lists 12 somatic variants for this specimen: 8 protein-altering or splice-affecting, 1 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Nonsense Mutation 1, Silent 1, Intron 1, 3'UTR 1, 3'Flank 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANK2 | c.2699G>A p.R900Q | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.055); catalogued as rs762658824, COSV52179662; called by muse, mutect2, varscan2
- ECEL1 | c.1933C>T p.R645* | Nonsense Mutation (SNP) | VAF 11/22 reads (50%) | catalogued as rs756675006, COSV58811983; called by muse, mutect2, varscan2
- IL5RA | c.367G>T p.G123W | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56522795; called by muse, mutect2, varscan2
- MGA | c.3158G>A p.R1053Q | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs991133548; called by muse, mutect2
- PHKA1 | c.3250G>A p.G1084R | Missense Mutation (SNP) | VAF 7/83 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1181595611, COSV100262707, COSV59804075; ClinVar: uncertain significance; called by muse, mutect2
- PLCH2 | c.251G>A p.R84H | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); catalogued as rs371340812; called by muse, mutect2, varscan2
- IGLV5-45 | c.368del p.S123del | Frame Shift Del (DEL) | VAF 40/131 reads (31%) | called by pindel, varscan2
- KREMEN1 | c.903G>C p.L301F (on ENST00000407188; = p.L303F on NM_032045.5) | Missense Mutation (SNP) | VAF 28/53 reads (53%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- AL358113.1 | c.171C>T p.N57= | Silent (SNP) | VAF 26/69 reads (38%) | catalogued as rs1038488938; called by muse, mutect2, varscan2
- CDC14B | c.161-1408G>A | Intron (SNP) | VAF 5/13 reads (38%) | called by muse, mutect2, varscan2
- NUDT14 | c.*51C>T | 3'UTR (SNP) | VAF 10/41 reads (24%) | catalogued as rs751012382; called by muse, mutect2, varscan2
- SNORD116-17 | chr15:25088333 C>T | 3'Flank (SNP) | VAF 26/52 reads (50%) | catalogued as rs774094106; called by muse, mutect2, varscan2
